Somatic mutation profile of tumor specimen TCGA-XE-AAOB-01A (aliquot TCGA-XE-AAOB-01A-11D-A435-10) from TCGA case TCGA-XE-AAOB, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Teratocarcinoma; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 27.1 years (9,907 days).
Specimen TCGA-XE-AAOB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b71a17b5-b693-4b3d-97e7-f6c419f3d0de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOB-10A (Blood Derived Normal), aliquot TCGA-XE-AAOB-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8687bd4b-ed0f-44f0-a40c-27590b6ab3d4

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FARSB | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759171456; called by muse, mutect2, varscan2
- HMCN1 | c.9127G>A p.E3043K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs747230633, COSV54878415, COSV54886798; called by muse, mutect2, varscan2
- KCNMA1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as rs142858967, COSV54238165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP19 | c.496T>G p.L166V | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2
- CERS5 | c.643del p.L215* | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- GRIN2B | c.2144A>T p.D715V | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- GRM8 | c.1382T>C p.F461S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR5A | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- MYH10 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF23 | c.740_741del p.S247* | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by pindel, varscan2
- PRRC2B | c.1784C>A p.S595Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.672G>A p.L224= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- DTX2 | c.477C>T p.H159= | Silent (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- PCDHB13 | c.588G>A p.V196= | Silent (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- KRT8P11 | n.901A>G | RNA (SNP) | VAF 5/52 reads (10%) | catalogued as rs1197798703; called by muse, mutect2, varscan2
